Somatic mutation profile of tumor specimen TCGA-EE-A182-06A (aliquot TCGA-EE-A182-06A-11D-A196-08) from TCGA case TCGA-EE-A182, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 85.2 years (31,124 days).
Specimen TCGA-EE-A182-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 385a7094-f14a-472a-800c-9629e73cb6df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A182-10A (Blood Derived Normal), aliquot TCGA-EE-A182-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/437493b6-0ad9-4daf-af51-29fa42217270

The open-access MAF lists 1,792 somatic variants for this specimen: 1,142 protein-altering or splice-affecting, 601 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,035, Silent 601, Nonsense Mutation 70, Intron 23, RNA 15, Frame Shift Del 11, Splice Site 11, Splice Region 7, 3'UTR 5, 3'Flank 4, Translation Start Site 3, Nonstop Mutation 2.

Variants (750 of 1,792; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs104894341, CM950082, COSV52230586; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNM2 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs121909091, CM053833, COSV58963902; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIT | c.1676T>C p.V559A | Missense Mutation (SNP) | VAF 18/67 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs121913517, CM013551, COSV55386973, COSV55388782, COSV55393324; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 30/102 reads (29%) | hotspot (GDC flag); catalogued as rs778405030, CM950845, COSV62197118; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.5350G>A p.E1784K (on ENST00000333535 / NM_198056.3; = p.E1783K on NM_000335.5) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as rs137854601, CM991128, COSV61117722; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A1CF | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.156); catalogued as rs781647376, COSV50972538; called by muse, mutect2, varscan2
- AADACL2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs765624984, COSV62930815; called by muse, mutect2, varscan2
- AADAT | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV61787349; called by muse, mutect2, varscan2
- ABCA6 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs1339645922, COSV52639777; called by muse, mutect2, varscan2
- ABCB5 | c.3398A>T p.N1133I (on ENST00000404938 / NM_001163941.2; = p.N688I on NM_178559.6) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51711707; called by muse, mutect2, varscan2
- ABCC10 | c.3233A>G p.Y1078C (on ENST00000372530 / NM_001198934.2; = p.Y1050C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55086571; called by muse, mutect2, varscan2
- ABCC12 | c.3806G>A p.R1269Q | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139931213; called by muse, mutect2, varscan2
- ABCD2 | c.1412T>C p.V471A | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV58052330, COSV58053458; called by muse, mutect2, varscan2
- ABCD2 | c.1405+1G>A p.X469_splice | Splice Site (SNP) | VAF 22/64 reads (34%) | catalogued as rs755130015, COSV58052337; called by muse, mutect2, varscan2
- ABCG1 | c.2027C>G p.A676G | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV59205505; called by mutect2, varscan2
- ABL1 | c.2911C>T p.P971S | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV59333318; called by muse, mutect2, varscan2
- ABLIM2 | c.1427C>T p.S476F (on ENST00000341937 / NM_001130084.2; = p.S425F on NM_032432.5) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV56405636; called by muse, varscan2
- ACADS | c.1129C>G p.P377A | Missense Mutation (SNP) | VAF 135/432 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV54369164; called by muse, mutect2, varscan2
- ACADSB | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 67/103 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV62550875; called by muse, mutect2, varscan2
- ACOT9 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV60537944; called by muse, mutect2, varscan2
- ACSL4 | c.178C>T p.R60C (on ENST00000340800 / NM_022977.2; = p.R19C on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61614756; called by muse, mutect2, varscan2
- ACSM1 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54636619; called by muse, mutect2, varscan2
- ACSM2B | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61658212; called by muse, mutect2, varscan2
- ACSM4 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68068059; called by muse, mutect2, varscan2
- ADAM19 | c.2450A>G p.N817S | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs769257964, COSV57431499; called by muse, mutect2, varscan2
- ADAM19 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.052); catalogued as COSV57431528; called by muse, mutect2, varscan2
- ADAM29 | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63664484; called by muse, mutect2, varscan2
- ADAMDEC1 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV56474930; called by muse, mutect2, varscan2
- ADAMTS12 | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV61263246, COSV61265283; called by muse, mutect2, varscan2
- ADAMTS18 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770474298, COSV51417346; called by muse, mutect2, varscan2
- ADAMTS20 | c.4702G>A p.E1568K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.767); catalogued as rs925998386, COSV67133124; called by muse, mutect2, varscan2
- ADAMTS20 | c.2954G>A p.G985E | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67133130; called by muse, mutect2, varscan2
- ADAMTS6 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1336373549, COSV66860675; called by muse, mutect2, varscan2
- ADAMTS9 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 139/572 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV55783060, COSV55792381; called by muse, mutect2, varscan2
- ADCY5 | c.3421G>A p.D1141N | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); catalogued as rs1199215589, COSV59194029; called by muse, mutect2, varscan2
- ADCY7 | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as rs755500712, COSV54267557; called by muse, mutect2, varscan2
- ADGRE1 | c.2410C>T p.L804F | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV51676695; called by muse, mutect2, varscan2
- ADGRF2 | c.1600T>A p.F534I (on ENST00000296862 / NM_001368115.2; = p.F466I on NM_153839.7) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57288897; called by muse, mutect2, varscan2
- ADGRG4 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV54958366; called by muse, mutect2, varscan2
- ADGRG4 | c.2207T>A p.F736Y | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54958376, COSV99797404; called by muse, mutect2, varscan2
- ADGRG4 | c.3583G>A p.G1195R | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV54958387; called by muse, mutect2, varscan2
- ADGRL3 | c.55G>A p.G19S (on ENST00000506720 / NM_001322402.2; = p.A19T on NM_015236.6) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.855); catalogued as COSV72268966; called by muse, mutect2, varscan2
- ADH1C | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs764088804, COSV72463457; called by muse, mutect2, varscan2
- ADH6 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52956502; called by muse, mutect2, varscan2
- ADH6 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756863693, COSV52955529; called by muse, mutect2, varscan2
- AFF4 | c.940A>C p.S314R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV54795674; called by muse, mutect2, varscan2
- AFM | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV56920363; called by muse, mutect2
- AGAP1 | c.2036C>T p.S679F (on ENST00000304032 / NM_001037131.3; = p.S626F on NM_014914.5) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV58328586; called by muse, mutect2, varscan2
- AGAP4 | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV71164929; called by muse, mutect2, varscan2
- AKAP4 | c.2189C>T p.S730L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV62074671; called by muse, mutect2, varscan2
- AKR1C3 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs192314534, COSV65910650; called by muse, mutect2, varscan2
- ALB | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV55738013; called by muse, mutect2, varscan2
- ALB | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); catalogued as COSV55738874; called by muse, mutect2, varscan2
- ALDH16A1 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.077); catalogued as COSV53194521; called by muse, mutect2, varscan2
- ALDH1B1 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs748522437, COSV66620040; called by muse, mutect2, varscan2
- ALDH3A1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV56735604; called by muse, mutect2, varscan2
- ALX4 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as rs778941350, COSV100241041; called by muse, varscan2
- ALX4 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100241042, COSV100241369; called by muse, mutect2, varscan2
- AMER1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV57656995, COSV57657427; called by muse, mutect2, varscan2
- ANGPT1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs868669098, COSV52433932; called by muse, mutect2, varscan2
- ANK1 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV55883932; called by muse, mutect2, varscan2
- ANK1 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs751082142, COSV55883941; called by muse, mutect2, varscan2
- ANK3 | c.13006G>A p.D4336N (on ENST00000280772 / NM_001320874.2; = p.D960N on NM_001149.3) | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV55062277; called by muse, mutect2, varscan2
- ANKIB1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV56062688; called by muse, mutect2, varscan2
- ANKLE1 | c.1204G>A p.E402K (on ENST00000394458; = p.E348K on NM_152363.6) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs772844407, COSV63920967; called by muse, mutect2, varscan2
- ANKRD27 | c.3098C>T p.P1033L | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs150349860, COSV60132493; called by muse, mutect2, varscan2
- ANKRD30A | c.2500G>A p.G834R (on ENST00000611781; = p.G778R on NM_052997.2) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV64612412, COSV99071049; called by muse, mutect2, varscan2
- ANO2 | c.320G>A p.G107E (on ENST00000356134 / NM_001278597.3; = p.G111E on NM_001278596.3) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.311); catalogued as COSV59026882; called by muse, mutect2, varscan2
- ANXA2 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV60317172; called by muse, mutect2
- AOAH | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV51743050; called by muse, mutect2, varscan2
- AOX1 | c.2557G>A p.G853R | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs1377988257, COSV101021924, COSV65980811; called by muse, varscan2
- AOX1 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs1454999351, COSV65982116; called by muse, varscan2
- APCS | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 104/187 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54817203; called by muse, mutect2, varscan2
- APLP1 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99383933; called by muse, mutect2
- APLP1 | c.461A>C p.E154A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV99383934; called by muse, mutect2
- APOA5 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99911293; called by muse, mutect2, varscan2
- APOB | c.8356G>A p.E2786K | Missense Mutation (SNP) | VAF 217/694 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs373774326; called by muse, mutect2, varscan2
- APOB | c.2816G>A p.G939D | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs1165406609, CM101114, COSV51938905; called by muse, mutect2, varscan2
- APOB | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51926765; called by muse, mutect2, varscan2
- APOH | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs898598847, COSV52773090; called by muse, mutect2, varscan2
- AQP2 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV52230597; called by muse, mutect2, varscan2
- ARHGAP10 | c.1662G>A p.M554I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60600719; called by muse, mutect2, varscan2
- ARHGAP26 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs182566788, COSV50831527; called by muse, mutect2, varscan2
- ARHGAP6 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.102); catalogued as COSV57292710, COSV57297169; called by muse, mutect2, varscan2
- ARHGAP9 | c.1239C>A p.F413L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV57363290; called by muse, mutect2, varscan2
- ARID2 | c.5431C>T p.L1811F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57605993; called by muse, mutect2
- ARMC4 | c.2220G>A p.W740* | Nonsense Mutation (SNP) | VAF 32/142 reads (23%) | catalogued as rs867142532, COSV59457421; called by muse, mutect2, varscan2
- ARMC4 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV59465239; called by muse, mutect2, varscan2
- ASAP1 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 70/264 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV63049697; called by muse, mutect2, varscan2
- ASNSD1 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53623888; called by muse, mutect2, varscan2
- ASXL2 | c.4147C>T p.P1383S | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.8); catalogued as COSV55460144; called by muse, mutect2, varscan2
- ASXL2 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs369212828; called by muse, mutect2, varscan2
- ATIC | c.731T>C p.L244S | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52693648; called by muse, mutect2, varscan2
- ATP1B4 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV54313190; called by muse, mutect2, varscan2
- ATP6V0A2 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 36/110 reads (33%) | catalogued as COSV57749846; called by muse, mutect2, varscan2
- ATP6V1E1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs775186565, COSV53657433; called by muse, mutect2, varscan2
- ATP8A1 | c.2909G>A p.G970E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV52528095; called by muse, mutect2, varscan2
- ATXN1 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV55219155; called by muse, mutect2, varscan2
- AVPR1A | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.02); catalogued as COSV54546993; called by muse, mutect2, varscan2
- AZGP1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.133); catalogued as COSV52798057; called by muse, mutect2
- BACH1 | c.427A>C p.K143Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV54519398; called by muse, mutect2, varscan2
- BAIAP2 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.1); catalogued as rs753906511, COSV58336270; called by muse, mutect2, varscan2
- BBS2 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766476238, COSV55326589; called by muse, mutect2, varscan2
- BCAP31 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998971015, COSV61451800; called by muse, mutect2, varscan2
- BCAS1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1392704375, COSV65085185, COSV65086859; called by muse, mutect2, varscan2
- BCL11A | c.2080C>T p.P694S (on ENST00000335712 / NM_001365609.1; = p.P728S on NM_018014.4) | Missense Mutation (SNP) | VAF 118/411 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.235); catalogued as COSV59631435; called by muse, mutect2, varscan2
- BCOR | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60700199; called by muse, mutect2, varscan2
- BCR | c.3053C>T p.T1018I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs1198854368, COSV59932210; called by muse, mutect2
- BEND5 | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV65717570; called by muse, mutect2, varscan2
- BEST3 | c.1324A>T p.N442Y | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV58302170; called by muse, mutect2, varscan2
- BIRC6 | c.14153C>T p.P4718L | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV70200274; called by muse, mutect2, varscan2
- BMP1 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs73670368, COSV60480186; called by muse, mutect2, varscan2
- BMP15 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV53140815, COSV53141751; called by muse, mutect2, varscan2
- BMS1 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as COSV65734208; called by muse, mutect2, varscan2
- BNC1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV61757791; called by muse, mutect2, varscan2
- BNIP5 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as rs1423852186, COSV71325590; called by muse, mutect2, varscan2
- BOD1L1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50017770; called by muse, mutect2, varscan2
- BRDT | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV62865390; called by muse, mutect2, varscan2
- BRINP3 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66527282; called by muse, mutect2, varscan2
- BRIP1 | c.2948T>G p.I983S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.013); catalogued as COSV52001004, COSV52002200; called by muse, mutect2, varscan2
- BRWD1 | c.4490C>T p.S1497F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV60897195; called by muse, mutect2, varscan2
- BRWD3 | c.3991C>T p.L1331F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.713); catalogued as COSV64749209; called by muse, mutect2, varscan2
- BRWD3 | c.3851C>T p.S1284L | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV64749221; called by muse, mutect2, varscan2
- BRWD3 | c.2418T>A p.N806K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.028); catalogued as COSV100955876, COSV64749231; called by muse, mutect2, varscan2
- BSND | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1263713669, COSV100987645, COSV64870775; called by muse, mutect2, varscan2
- BST1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); catalogued as COSV53947174; called by muse, mutect2, varscan2
- BTBD8 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV61546629; called by muse, mutect2, varscan2
- BTNL3 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs375825455; called by muse, mutect2, varscan2
- C10orf120 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs771671807, COSV61492143; called by muse, mutect2, varscan2
- C1QTNF1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100189748, COSV59262311; called by muse, mutect2, varscan2
- C1orf216 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52046987; called by muse, mutect2, varscan2
- C3 | c.4148C>A p.T1383N | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs139100972, CM108971; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- C4A | c.2470C>T p.P824S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101418330; called by mutect2, varscan2
- C6 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs369381506; called by muse, mutect2, varscan2
- C7 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.373); catalogued as COSV57475438; called by muse, mutect2, varscan2
- C8B | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as rs202207968; called by muse, mutect2, varscan2
- C8orf34 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61382653; called by muse, mutect2, varscan2
- CACNA1C | c.2299A>T p.K767* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV59728535; called by muse, mutect2, varscan2
- CACNA1E | c.6128G>A p.S2043N (on ENST00000367573 / NM_001205293.3; = p.S2000N on NM_000721.4) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as COSV62400040; called by muse, mutect2, varscan2
- CACNA1E | c.6578C>T p.S2193F (on ENST00000367573 / NM_001205293.3; = p.S2150F on NM_000721.4) | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs1025826185, COSV62400052, COSV62411592; called by muse, mutect2, varscan2
- CACNA1F | c.3195T>G p.S1065R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV59904965; called by muse, mutect2, varscan2
- CALCRL | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV66475403; called by muse, mutect2, varscan2
- CALCRL | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66475408, COSV66476230; called by muse, mutect2, varscan2
- CALHM1 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV53294382; called by muse, mutect2, varscan2
- CALN1 | c.331C>T p.R111C (on ENST00000329008 / NM_001017440.3; = p.R153C on NM_031468.4) | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1473772101, COSV61127841, COSV61144822; called by muse, mutect2, varscan2
- CAPZA3 | c.510G>A p.W170* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as rs868010711, COSV56850834; called by muse, mutect2, varscan2
- CARD11 | c.687C>T p.I229= | Splice Region (SNP) | VAF 24/96 reads (25%) | catalogued as rs369930171; called by muse, mutect2, varscan2
- CCBE1 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs763623450, COSV101232816; called by muse, mutect2, varscan2
- CCBE1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs115982879, COSV67949322; called by muse, mutect2, varscan2
- CCDC102B | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); catalogued as COSV60144441; called by muse, mutect2, varscan2
- CCDC106 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs1366277489, COSV58272688; called by muse, mutect2, varscan2
- CCDC116 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV53037997; called by muse, mutect2, varscan2
- CCDC142 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.065); catalogued as COSV51778397, COSV99282436; called by muse, mutect2, varscan2
- CCDC178 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100284605, COSV55777457, COSV55796096; called by muse, mutect2, varscan2
- CCDC185 | c.1808G>A p.S603N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs1446644407, COSV64821061; called by muse, mutect2, varscan2
- CCDC83 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1343772118, COSV54701403; called by muse, mutect2, varscan2
- CCDC86 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1031629655, COSV57125385; called by muse, mutect2, varscan2
- CCDC88B | c.4139C>T p.S1380F | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs552415020, COSV53703947; called by muse, mutect2, varscan2
- CCDC89 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 53/122 reads (43%) | catalogued as COSV57034223; called by muse, mutect2, varscan2
- CCHCR1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100883970, COSV66161365; called by muse, mutect2, varscan2
- CCNB3 | c.3964C>T p.P1322S | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs868978383, COSV52073984; called by muse, mutect2, varscan2
- CCNYL1 | c.716C>T p.A239V (on ENST00000295414 / NM_001330218.2; = p.A169V on NM_152523.2) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV54940607; called by muse, mutect2, varscan2
- CCR2 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 133/406 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.589); catalogued as COSV52749045; called by muse, mutect2, varscan2
- CCR2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as COSV52747728; called by muse, mutect2, varscan2
- CD163 | c.3149C>T p.S1050F | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs867128232, COSV63133408; called by muse, mutect2, varscan2
- CD163 | c.2330G>A p.G777E | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63133423; called by muse, mutect2, varscan2
- CD1A | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV56862226; called by muse, mutect2, varscan2
- CD86 | c.181G>A p.E61K (on ENST00000330540 / NM_175862.5; = p.E55K on NM_006889.4) | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV52605248; called by muse, mutect2, varscan2
- CDC20B | c.940C>T p.H314Y | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57053410; called by muse, mutect2, varscan2
- CDH17 | c.1282+2T>C p.X428_splice | Splice Site (SNP) | VAF 16/45 reads (36%) | catalogued as COSV50330266; called by muse, mutect2, varscan2
- CDH20 | c.6G>A p.W2* | Nonsense Mutation (SNP) | VAF 32/103 reads (31%) | catalogued as COSV53011357; called by muse, mutect2, varscan2
- CDH23 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.969); catalogued as COSV54928952; called by muse, mutect2, varscan2
- CDH7 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59881209, COSV59881942, COSV59885320; called by muse, mutect2, varscan2
- CDH7 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.519); catalogued as COSV59882419; called by muse, mutect2, varscan2
- CDHR1 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV60563195; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5119C>T p.P1707S | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV62574985; called by muse, mutect2, varscan2
- CEACAM7 | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50073167; called by muse, mutect2, varscan2
- CELSR3 | c.9604G>A p.E3202K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as rs756230263, COSV99373375; called by muse, mutect2
- CEP135 | c.2797C>T p.Q933* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV57259960, COSV57260710; called by muse, mutect2
- CEP89 | c.1676T>C p.L559S | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV59864958; called by muse, mutect2, varscan2
- CFAP100 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as rs200815085, COSV61504003; called by muse, mutect2, varscan2
- CFAP46 | c.7369G>A p.G2457R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99584590; called by muse, mutect2, varscan2
- CFAP52 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs767415440, COSV55345633; called by muse, mutect2, varscan2
- CFAP52 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55345685; called by muse, mutect2, varscan2
- CFAP54 | c.7702C>G p.Q2568E | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.097); catalogued as COSV61572628; called by muse, mutect2, varscan2
- CFAP70 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs751444822, COSV60282272; called by muse, mutect2, varscan2
- CHD4 | c.5006C>T p.P1669L (on ENST00000357008 / NM_001363606.2; = p.P1680L on NM_001273.5) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.192); catalogued as COSV100537885; called by muse, mutect2, varscan2
- CHL1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs767382114, COSV56595575; called by muse, mutect2, varscan2
- CHL1 | c.854G>A p.R285K (on ENST00000397491 / NM_001253387.1; = p.R301K on NM_006614.4) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.293); catalogued as rs1559293111, COSV56595089; called by muse, mutect2
- CHST2 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58885905; called by muse, mutect2
- CHSY1 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM108422, COSV54253936; called by muse, mutect2, varscan2
- CLCN5 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV56584645; called by muse, mutect2, varscan2
- CLCN6 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV100411869; called by muse, mutect2, varscan2
- CLCN6 | c.2213C>T p.P738L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV56743057; called by muse, mutect2, varscan2
- CLEC4C | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV63582527; called by muse, mutect2, varscan2
- CLGN | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.24); catalogued as rs1431627800, COSV57775095; called by muse, mutect2, varscan2
- CLIP2 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV56280406, COSV56284743; called by muse, mutect2, varscan2
- CLSTN1 | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV63648593; called by muse, mutect2, varscan2
- CNGA4 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV66006191; called by muse, mutect2, varscan2
- CNGB3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV60685142; called by muse, mutect2, varscan2
- CNOT6 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.597); catalogued as COSV56161955; called by muse, mutect2, varscan2
- CNTN5 | c.2450G>A p.G817E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54318615, COSV54371499, COSV99682311; called by muse, mutect2, varscan2
- CNTN5 | c.3236C>T p.S1079F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV54318630, COSV99677873; called by muse, mutect2, varscan2
- CNTRL | c.3620G>A p.S1207N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs754136974, COSV53048264; called by muse, mutect2, varscan2
- COBLL1 | c.3086C>T p.P1029L (on ENST00000392717; = p.P991L on NM_014900.5) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV52069481; called by muse, mutect2, varscan2
- COL12A1 | c.9118C>T p.P3040S | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV59397729; called by muse, mutect2, varscan2
- COL15A1 | c.2300G>A p.G767E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200410708, COSV66645978; called by muse, mutect2, varscan2
- COL21A1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as rs867948640, COSV55159384; called by muse, mutect2, varscan2
- COL28A1 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68082618; called by muse, mutect2, varscan2
- COL28A1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as rs775450045, COSV68082620; called by muse, mutect2, varscan2
- COL4A2 | c.4180C>T p.P1394S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV64629293; called by muse, mutect2, varscan2
- COL4A6 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57868680; called by muse, mutect2, varscan2
- COL5A1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV65670041; called by muse, mutect2, varscan2
- COL5A2 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754429372, COSV66410611; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.3940C>T p.P1314S | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV53412314; called by muse, mutect2, varscan2
- COL6A2 | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV56007298; called by muse, mutect2, varscan2
- COL6A3 | c.9028G>A p.E3010K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV55089802; called by muse, mutect2, varscan2
- COL6A3 | c.3007G>A p.G1003R | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as COSV55093112; called by muse, mutect2, varscan2
- CPA3 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1429769999, COSV56044181; called by muse, mutect2, varscan2
- CPAMD8 | c.3452C>T p.T1151I (on ENST00000651564; = p.T1104I on NM_015692.5) | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV71596732; called by muse, mutect2, varscan2
- CPEB3 | c.1184T>C p.F395S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.147); catalogued as COSV56457503; called by muse, mutect2, varscan2
- CPLX4 | c.74A>T p.N25I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as rs1456698351, COSV55313825; called by muse, mutect2, varscan2
- CPN1 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64942388; called by muse, mutect2, varscan2
- CPNE4 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as rs1387944113, COSV70195246; called by muse, mutect2, varscan2
- CPT1A | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55757053; called by muse, mutect2, varscan2
- CR1L | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs1354517364, COSV54327194; called by muse, mutect2, varscan2
- CR2 | c.1005G>A p.W335* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV65506855; called by muse, mutect2, varscan2
- CREBBP | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV52126772; called by muse, mutect2, varscan2
- CREBRF | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV51633493; called by muse, mutect2, varscan2
- CRNKL1 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV55632797; called by muse, mutect2, varscan2
- CS | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV57525039; called by muse, mutect2, varscan2
- CSF2RA | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.117); catalogued as rs201854740, COSV100818008, COSV62623853; called by muse, mutect2, varscan2
- CSMD1 | c.1124C>T p.S375L (on ENST00000520002; = p.S374L on NM_033225.6) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs762593887, COSV68165271; called by muse, mutect2, varscan2
- CSMD2 | c.7609C>T p.P2537S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53880756, COSV53920629; called by muse, mutect2, varscan2
- CSMD2 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as rs748835820, COSV53895728, COSV53920668; called by muse, mutect2, varscan2
- CSTL1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as COSV55678252; called by muse, mutect2, varscan2
- CSTL1 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as rs746184924, COSV55677651; called by muse, mutect2, varscan2
- CTTNBP2 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs547423580, COSV50409553; called by muse, mutect2, varscan2
- CUEDC1 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64226576; called by muse, mutect2, varscan2
- CWH43 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748858503, COSV56939704; called by muse, mutect2, varscan2
- CXorf56 | c.448G>A p.E150K (on ENST00000536133 / NM_001170570.2; = p.E164K on NM_022101.4) | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57438444, COSV57438726; called by muse, mutect2, varscan2
- CYB5A | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs760465035, COSV55022173; called by muse, mutect2, varscan2
- CYP2C8 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64877530; called by muse, mutect2, varscan2
- CYP2C9 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs367826293, CM155864; called by muse, mutect2, varscan2
- CYP2C9 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53246736; called by muse, mutect2, varscan2
- CYP4F12 | c.1223T>A p.L408H | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61174273; called by muse, mutect2, varscan2
- CYP4F12 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61173162; called by muse, mutect2, varscan2
- CYP4F2 | c.399G>A p.G133= | Splice Region (SNP) | VAF 37/102 reads (36%) | catalogued as COSV50000402; called by muse, mutect2, varscan2
- CYP4F22 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as COSV54109121; called by muse, mutect2, varscan2
- CYP4X1 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64151013; called by muse, mutect2, varscan2
- CYP4X1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV64151019; called by muse, mutect2, varscan2
- CYP4X1 | c.1448G>A p.R483K | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs988769573, COSV64151024; called by muse, mutect2, varscan2
- CYP8B1 | c.842G>A p.W281* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV60226637; called by muse, mutect2, varscan2
- DCAF12L2 | c.1306T>C p.Y436H | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63582163; called by muse, mutect2, varscan2
- DCC | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV59108195; called by muse, mutect2, varscan2
- DCC | c.3393G>A p.K1131= | Splice Region (SNP) | VAF 14/47 reads (30%) | catalogued as COSV71427284; called by muse, mutect2, varscan2
- DCC | c.3486G>A p.M1162I | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV71433464; called by muse, mutect2, varscan2
- DCC | c.4240G>A p.E1414K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV71433465; called by muse, mutect2, varscan2
- DCDC1 | c.5181G>T p.M1727I (on ENST00000597505 / NM_001367979.1; = p.M834I on NM_020869.3) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.236); catalogued as COSV57999796; called by muse, varscan2
- DCLRE1B | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV65812956; called by muse, mutect2, varscan2
- DDR1 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV61321684; called by muse, mutect2, varscan2
- DDX21 | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV62555817; called by muse, mutect2, varscan2
- DDX60L | c.4833G>A p.W1611* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV52714969; called by muse, mutect2, varscan2
- DENND1C | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1276311525, COSV57568833; called by muse, mutect2, varscan2
- DENND4A | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101475326; called by muse, mutect2, varscan2
- DGAT2L6 | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV60717989; called by muse, mutect2, varscan2
- DHDDS | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52577019; called by muse, mutect2, varscan2
- DHX34 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1243096657, COSV60894795; called by muse, mutect2
- DHX38 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as rs780039631, COSV51701607; called by muse, mutect2, varscan2
- DHX38 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs749000951, COSV51699248; called by muse, mutect2, varscan2
- DHX38 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778940669, COSV51698507; called by muse, mutect2, varscan2
- DIDO1 | c.4952C>T p.S1651L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs780424414, COSV56625122; called by muse, mutect2, varscan2
- DIP2C | c.2996C>T p.A999V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1476468047, COSV55161668; called by muse, varscan2
- DISP2 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.76); catalogued as rs1156310523, COSV99139933; called by muse, mutect2, varscan2
- DLEC1 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV57300965; called by muse, mutect2, varscan2
- DMRT3 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs778998093, COSV51905166; called by muse, mutect2, varscan2
- DNAH1 | c.8965C>T p.P2989S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV70230044; called by muse, mutect2
- DNAH11 | c.5176G>A p.E1726K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs373580829, COSV60957278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.11167G>A p.D3723N | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.139); catalogued as COSV66720710; called by muse, mutect2, varscan2
- DNAH3 | c.3826C>T p.H1276Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV54527494; called by muse, mutect2
- DNAH7 | c.7506+1G>A p.X2502_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as rs374158976; called by muse, varscan2
- DNAH7 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.957); catalogued as rs1172086537, COSV56768809; called by muse, mutect2, varscan2
- DNAH7 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs192646926; called by muse, mutect2, varscan2
- DNAH9 | c.11017G>A p.E3673K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV52339281; called by muse, mutect2, varscan2
- DNAJA3 | c.1438T>G p.S480A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.97); catalogued as COSV52162272; called by muse, mutect2, varscan2
- DNAJB11 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.735); catalogued as COSV54002863; called by muse, mutect2, varscan2
- DNAJB2 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV60676894; called by muse, mutect2, varscan2
- DNAJC13 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53452037; called by muse, mutect2, varscan2
- DNALI1 | c.430C>T p.P144S (on ENST00000296218; = p.P122S on NM_003462.5) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs959736369, COSV56170201; called by muse, mutect2, varscan2
- DNALI1 | c.475C>T p.R159W (on ENST00000296218; = p.R137W on NM_003462.5) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768925360, COSV56170210; called by muse, mutect2, varscan2
- DOCK10 | c.3328C>T p.P1110S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs779705781, COSV51417491; called by muse, mutect2, varscan2
- DPEP1 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV55360656; called by muse, mutect2, varscan2
- DPP10 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59686283, COSV59692696; called by muse, mutect2, varscan2
- DRD3 | c.687T>G p.S229R | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.786); catalogued as COSV55680660; called by muse, mutect2, varscan2
- DROSHA | c.2093C>T p.S698F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV60777510; called by muse, mutect2, varscan2
- DSC3 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64573401; called by muse, mutect2
- DSG1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57134255; called by muse, mutect2, varscan2
- DSG1 | c.1783C>T p.H595Y | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57136234; called by muse, mutect2, varscan2
- DSG1 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.421); catalogued as rs371822501; called by muse, mutect2, varscan2
- DSG3 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.217); catalogued as rs267605161, COSV57126970; called by muse, mutect2, varscan2
- DSG3 | c.2708G>A p.G903E | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.421); catalogued as COSV57126981; called by muse, mutect2, varscan2
- DSG4 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs868142301, COSV57392836; called by muse, mutect2, varscan2
- DSP | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as rs759084237, COSV101131211, COSV65793314; called by muse, mutect2, varscan2
- DST | c.16208C>T p.S5403F (on ENST00000361203 / NM_001374722.1; = p.S2991F on NM_015548.5) | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55019667; called by muse, mutect2, varscan2
- DUOX2 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV66532626; called by muse, mutect2, varscan2
- DUSP9 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV61438074; called by muse, mutect2, varscan2
- DYSF | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs1559138477, COSV50448716; called by muse, mutect2, varscan2
- DYSF | c.3598G>A p.D1200N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50448754; called by muse, mutect2, varscan2
- DZANK1 | c.1574T>C p.V525A (on ENST00000262547 / NM_001099407.1; = p.V332A on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV52752183; called by muse, mutect2, varscan2
- EAF2 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV56544715; called by muse, mutect2, varscan2
- EDDM3A | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779330097, COSV58795209; called by muse, mutect2
- EEF1A2 | c.238T>C p.F80L | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.176); catalogued as COSV53206580; called by muse, varscan2
- EFCAB5 | c.3823A>T p.M1275L | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.144); catalogued as COSV57931416; called by muse, mutect2, varscan2
- EFCAB6 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs150224112; called by muse, mutect2, varscan2
- EGFL6 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as COSV63634140; called by muse, mutect2, varscan2
- EGFL6 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.334); catalogued as rs780194370, COSV63633283; called by muse, mutect2, varscan2
- EGFLAM | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); catalogued as rs1236101728, COSV59305286; called by muse, mutect2, varscan2
- EIF4G1 | c.2270C>T p.T757I (on ENST00000346169 / NM_198241.3; = p.T562I on NM_004953.5) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59991542; called by muse, mutect2
- ELK3 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV57385882, COSV99957596; called by muse, mutect2, varscan2
- ELOVL3 | c.113T>A p.F38Y | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as COSV100892791; called by muse, mutect2, varscan2
- ELOVL3 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs769840453, COSV100892727, COSV64174564; called by muse, mutect2, varscan2
- ELSPBP1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV60413910; called by muse, mutect2, varscan2
- EML2 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1466778775, COSV55600294; called by muse, mutect2, varscan2
- ENAM | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV68536137; called by muse, mutect2, varscan2
- ENGASE | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100285764; called by muse, mutect2, varscan2
- ENTHD1 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57321204; called by muse, mutect2, varscan2
- ENTHD1 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs752651560, COSV57321215; called by muse, mutect2, varscan2
- ENTPD7 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV65112426; called by muse, mutect2, varscan2
- EP300 | c.469C>G p.P157A | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.205); catalogued as COSV99608370; called by muse, mutect2, varscan2
- EP300 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV99608371; called by muse, mutect2, varscan2
- EPB41L4B | c.2663G>A p.R888K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV65803459; called by muse, mutect2, varscan2
- EPHA3 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.089); catalogued as COSV60702588; called by muse, mutect2, varscan2
- EPHA7 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV65184485; called by muse, mutect2, varscan2
- EPRS1 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65099504; called by muse, mutect2, varscan2
- ERGIC1 | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101194879; called by muse, varscan2
- ERGIC1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101194880; called by muse, varscan2
- ESCO2 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs557813179, COSV59414946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESM1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV67318636; called by muse, mutect2, varscan2
- ETFA | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1189282229, COSV51211689; called by muse, mutect2, varscan2
- EVPL | c.2983G>A p.V995M | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV56912240; called by muse, mutect2, varscan2
- EWSR1 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); catalogued as rs1324909435, COSV58423082; called by muse, mutect2
- EXOSC7 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 26/81 reads (32%) | catalogued as rs1471027850, COSV55556895; called by muse, mutect2, varscan2
- FAAP100 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs754927886, COSV58367968; called by muse, mutect2, varscan2
- FAM135B | c.4035G>A p.M1345I | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52705063; called by muse, mutect2, varscan2
- FAM170A | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as COSV58925583; called by muse, mutect2, varscan2
- FAM214A | c.2579T>G p.I860S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV55924867; called by muse, mutect2, varscan2
- FAM47A | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV60497510; called by muse, mutect2, varscan2
- FAM47C | c.1571C>A p.P524Q | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.732); catalogued as COSV63727267; called by muse, mutect2, varscan2
- FAM72A | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 148/328 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV57917900, COSV57918312; called by muse, mutect2, varscan2
- FAM83G | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV58758946; called by muse, mutect2, varscan2
- FAM90A1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.14); catalogued as rs777961138, COSV56710265; called by muse, mutect2, varscan2
- FARP1 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100130496; called by muse, mutect2, varscan2
- FAT3 | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 169/392 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs370640653; called by muse, mutect2, varscan2
- FAT4 | c.11899C>T p.P3967S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100628417; called by mutect2, varscan2
- FAT4 | c.13789G>A p.E4597K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1347852459, COSV58689889; called by muse, mutect2, varscan2
- FBN2 | c.5205G>A p.M1735I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as rs1200593252, COSV52519407; called by muse, mutect2, varscan2
- FBP1 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs543540498, COSV64689404; called by muse, mutect2, varscan2
- FBXO21 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57973271; called by muse, varscan2
- FBXW10 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as rs1014732931, COSV100111397; called by muse, mutect2, varscan2
- FER1L6 | c.3997G>A p.D1333N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs139878625, COSV67550565; called by muse, mutect2, varscan2
- FER1L6 | c.5365G>A p.E1789K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762512675, COSV67550569; called by muse, mutect2, varscan2
- FEZF1 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58658996; called by muse, mutect2
- FFAR1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.082); catalogued as rs372751491; called by muse, mutect2, varscan2
- FGA | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.158); catalogued as COSV57397058; called by muse, mutect2, varscan2
- FGF16 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV71546216; called by muse, mutect2, varscan2
- FGFR1 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.012); catalogued as COSV58336208; called by muse, mutect2, varscan2
- FILIP1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 77/142 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1046337978, COSV52724428; called by muse, mutect2, varscan2
- FKBP15 | c.2053G>A p.G685S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53035759; called by muse, mutect2
- FLG | c.4241G>A p.G1414E | Missense Mutation (SNP) | VAF 108/570 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV64241862; called by muse, mutect2, varscan2
- FLG | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.068); catalogued as COSV64239366; called by muse, mutect2, varscan2
- FLG2 | c.5099G>A p.G1700E | Missense Mutation (SNP) | VAF 264/475 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.132); catalogued as COSV66167693; called by muse, mutect2, varscan2
- FLG2 | c.4451G>A p.G1484E | Missense Mutation (SNP) | VAF 352/659 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV66169348; called by muse, mutect2, varscan2
- FLNA | c.7943G>T p.*2648Lext*81 (on ENST00000369850 / NM_001110556.2; = p.*2640Lext*81 on NM_001456.3) | Nonstop Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV61036883; called by muse, mutect2, varscan2
- FLT1 | c.2947G>T p.E983* | Nonsense Mutation (SNP) | VAF 39/146 reads (27%) | catalogued as COSV56730322; called by muse, mutect2, varscan2
- FMN2 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV60433523; called by muse, mutect2, varscan2
- FMN2 | c.2887G>A p.G963S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV60433528, COSV60438616; called by muse, varscan2
- FMNL3 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.814); catalogued as COSV53303065; called by muse, mutect2, varscan2
- FOLR1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV56616313; called by muse, mutect2, varscan2
- FOXN1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as rs368261937; called by muse, mutect2, varscan2
- FRAS1 | c.6416C>T p.S2139F | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53617529; called by muse, mutect2, varscan2
- FRMD1 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.218); catalogued as COSV51962055; called by muse, mutect2, varscan2
- FRMD7 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 139/460 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV53746693; called by muse, mutect2, varscan2
- FRMPD2 | c.2176G>T p.G726C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.527); catalogued as COSV59718924; called by muse, varscan2
- FRMPD4 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); catalogued as rs147167664, COSV66213829; called by muse, mutect2, varscan2
- FRMPD4 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV66216525; called by muse, mutect2, varscan2
- FTMT | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV58420532; called by muse, mutect2, varscan2
- FZD7 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV53809332, COSV53809789; called by muse, mutect2, varscan2
- GABRA6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377669113; called by muse, mutect2, varscan2
- GABRB2 | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs780623765, COSV50916672; called by muse, mutect2, varscan2
- GABRE | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV64819959; called by muse, mutect2, varscan2
- GABRR3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.799); catalogued as rs773953288, COSV72084135; called by muse, mutect2, varscan2
- GADL1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.026); catalogued as COSV56977316; called by muse, varscan2
- GALNT17 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV61149361, COSV61166524; called by muse, mutect2, varscan2
- GALNT8 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV52898176; called by muse, mutect2, varscan2
- GDF9 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51526386; called by muse, mutect2, varscan2
- GHR | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV50115458, COSV99039096; called by muse, mutect2, varscan2
- GIGYF1 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs746880791, COSV51942923; called by muse, mutect2, varscan2
- GIMAP1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.094); catalogued as COSV56188484; called by muse, mutect2, varscan2
- GIMAP5 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.349); catalogued as rs756285302, COSV57530085; called by muse, mutect2, varscan2
- GIMAP6 | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 45/242 reads (19%) | catalogued as rs1411178132, COSV61033716, COSV61034517; called by muse, mutect2, varscan2
- GIMAP7 | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs80028286, COSV57959608; called by muse, mutect2, varscan2
- GIMAP8 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as COSV56231997; called by muse, mutect2, varscan2
- GJA4 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs768388317, COSV60725506; called by muse, mutect2, varscan2
- GJB5 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58355424; called by muse, mutect2, varscan2
- GJD2 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 92/272 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.162); catalogued as COSV51747898; called by muse, mutect2, varscan2
- GLDN | c.1521C>G p.N507K | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as COSV59090662; called by muse, mutect2, varscan2
- GLRB | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV52418049; called by muse, mutect2, varscan2
- GLUD2 | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV60152113; called by muse, mutect2, varscan2
- GMEB1 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV53794888; called by muse, mutect2, varscan2
- GMEB2 | c.1581C>G p.H527Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV56607497, COSV99823464; called by muse, mutect2, varscan2
- GPC5 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV65603899; called by muse, mutect2, varscan2
- GPHN | c.1450C>T p.L484F (on ENST00000315266 / NM_001377519.1; = p.L517F on NM_020806.5) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138042556, COSV59476441; called by muse, mutect2, varscan2
- GPR149 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV67667786; called by muse, mutect2, varscan2
- GPR149 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV67667473; called by muse, mutect2, varscan2
- GPR156 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs113424982, COSV100251219; called by muse, mutect2, varscan2
- GPR156 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV59941332; called by muse, mutect2, varscan2
- GPR34 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59368142; called by muse, mutect2, varscan2
- GPRIN2 | c.1173G>A p.W391* | Nonsense Mutation (SNP) | VAF 12/159 reads (8%) | catalogued as COSV100966366; called by muse, mutect2
- GRB14 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV55738924; called by muse, mutect2, varscan2
- GRIA3 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.768); catalogued as COSV52049101; called by muse, mutect2, varscan2
- GRIK1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546213634, COSV58718557; called by muse, mutect2, varscan2
- GRIN3A | c.1244G>A p.S415N | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV62452711; called by muse, mutect2, varscan2
- GRIN3A | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62452298, COSV62458577; called by muse, mutect2, varscan2
- GRM4 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as COSV65214417; called by muse, mutect2, varscan2
- GRM7 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs781373607, COSV63138807; called by muse, mutect2, varscan2
- GRM8 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58833155; called by muse, mutect2, varscan2
- GSPT2 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.363); catalogued as COSV61214513; called by muse, mutect2, varscan2
- GUCY2C | c.2737C>T p.P913S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53791118; called by muse, mutect2
- GUCY2F | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV54303618; called by muse, mutect2, varscan2
- GYPA | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51626824; called by muse, mutect2, varscan2
- GZMK | c.520A>C p.T174P | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV50245529; called by muse, mutect2, varscan2
- HACD4 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.299); catalogued as COSV72136726; called by muse, mutect2, varscan2
- HBD | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs868329922, COSV53082476; called by muse, mutect2, varscan2
- HDAC9 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777828245, COSV67770295; called by muse, mutect2, varscan2
- HDHD5 | c.800C>T p.T267M (on ENST00000336737 / NM_033070.3; = p.T237M on NM_017829.5) | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140503307, COSV50085273; called by muse, mutect2, varscan2
- HEATR4 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1566840941, COSV58573488; called by muse, mutect2, varscan2
- HECA | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV62769358; called by muse, mutect2, varscan2
- HECW1 | c.3145C>T p.P1049S | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67831534; called by muse, mutect2, varscan2
- HEPH | c.3034C>T p.R1012W (on ENST00000343002; = p.R745W on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1205946514, COSV57965458; called by muse, mutect2, varscan2
- HEPH | c.3245-1G>A p.X1082_splice (on ENST00000343002; = p.X815_splice on NM_014799.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 23/63 reads (37%) | catalogued as rs1156588740, COSV57965475; called by muse, mutect2, varscan2
- HERC1 | c.9667C>T p.R3223* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV71247813; called by muse, mutect2
- HERC2 | c.7571C>T p.S2524F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV55327972; called by muse, mutect2, varscan2
- HHIP | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as rs756314080, COSV56840358; called by muse, mutect2, varscan2
- HHLA2 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); catalogued as rs868050439, COSV63316629; called by muse, mutect2, varscan2
- HIPK4 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV52521710; called by muse, mutect2, varscan2
- HMCN1 | c.12115C>T p.P4039S | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV54907414; called by muse, mutect2, varscan2
- HMGB4 | c.536G>A p.R179K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53920687; called by muse, mutect2, varscan2
- HMGCLL1 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51446004; called by muse, mutect2, varscan2
- HPS1 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV57268342; called by muse, mutect2, varscan2
- HRG | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV51646076; called by muse, mutect2, varscan2
- HRNR | c.8465G>A p.G2822E | Missense Mutation (SNP) | VAF 102/170 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs751655859, COSV64259097; called by muse, mutect2, varscan2
- HROB | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs758769585, COSV55369843; called by muse, mutect2, varscan2
- HS3ST4 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58818594; called by muse, mutect2, varscan2
- HSPA1L | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 223/698 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV65149133; called by muse, mutect2, varscan2
- HYDIN | c.12337G>A p.E4113K | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.033); catalogued as COSV66637950; called by muse, mutect2, varscan2
- HYDIN | c.7180G>A p.D2394N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.55); catalogued as rs754663231, COSV99992722; called by muse, mutect2, varscan2
- IDH3B | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1296328416, COSV66483418; called by muse, mutect2, varscan2
- IFIT2 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.514); catalogued as COSV51078901; called by muse, mutect2, varscan2
- IGBP1 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV60556541; called by muse, mutect2, varscan2
- IGHMBP2 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV54823114; called by muse, mutect2, varscan2
- IGHV3-11 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 104/298 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.725); catalogued as rs782705452; called by muse, varscan2
- IGHV4-34 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs3814933; called by muse, varscan2
- IGKV1-8 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 72/256 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs1239351171; called by muse, mutect2, varscan2
- IGSF10 | c.6067G>A p.G2023R | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56382075; called by muse, mutect2, varscan2
- IGSF9B | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100317959, COSV58068843; called by muse, mutect2, varscan2
- IL17B | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV51003049; called by muse, mutect2, varscan2
- IL22RA1 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV54629035; called by muse, mutect2, varscan2
- IL9R | c.735G>A p.W245* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV54900329; called by muse, mutect2, varscan2
- INHBB | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777704323, CM157393, COSV54677495; called by muse, mutect2, varscan2
- INO80 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0.039); catalogued as COSV62738525, COSV62738817; called by muse, mutect2, varscan2
- INSRR | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.805); catalogued as rs756592765, COSV63874376; called by muse, mutect2, varscan2
- INVS | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as rs1369878554, COSV52437834, COSV52445171; called by muse, mutect2, varscan2
- IPO4 | c.2842C>T p.L948F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV61016966; called by muse, mutect2, varscan2
- IREB2 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as COSV51923615; called by muse, mutect2, varscan2
- IRF5 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV50858238, COSV99978001; called by muse, mutect2, varscan2
- ISM2 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.518); catalogued as COSV53635508; called by muse, mutect2, varscan2
- ITIH5 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53667899; called by muse, mutect2, varscan2
- ITPKB | c.2112G>A p.M704I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV55263273; called by muse, mutect2, varscan2
- JADE3 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV54467264; called by muse, mutect2, varscan2
- JCAD | c.3341C>T p.P1114L | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV100948321; called by muse, mutect2, varscan2
- KALRN | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs546138856, COSV53765041; called by muse, mutect2, varscan2
- KCMF1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69053984; called by muse, mutect2, varscan2
- KCNB2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73048713; called by muse, mutect2, varscan2
- KCND1 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV54414485; called by muse, mutect2, varscan2
- KCND2 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.967); catalogued as COSV58583829; called by muse, mutect2, varscan2
- KCNH5 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV59762878; called by muse, mutect2, varscan2
- KCNH8 | c.2753C>T p.S918F | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.653); catalogued as rs767497421, COSV60466316; called by muse, mutect2, varscan2
- KCNN3 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.926); catalogued as COSV55218772; called by muse, mutect2
- KCNQ3 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV66472775; called by muse, mutect2, varscan2
- KCNQ5 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59663959; called by muse, mutect2, varscan2
- KCNV1 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV52086584, COSV99819484; called by muse, mutect2, varscan2
- KCTD19 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV58573270; called by muse, mutect2, varscan2
- KEL | c.401-1G>A p.X134_splice | Splice Site (SNP) | VAF 12/87 reads (14%) | catalogued as rs745736040, COSV62335644; called by muse, mutect2
- KHDRBS1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV56982217; called by muse, mutect2, varscan2
- KIAA0408 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs140703945, COSV100846801; called by muse, mutect2, varscan2
- KIAA1109 | c.8078C>T p.S2693L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as COSV52677100; called by muse, mutect2, varscan2
- KIAA1210 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.319); catalogued as rs1158367171, COSV68177610, COSV68177715; called by muse, mutect2, varscan2
- KIF1C | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs777832656, COSV57903839; called by muse, mutect2
- KIF21B | c.1535G>A p.R512K | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV100144516, COSV59759320; called by muse, mutect2, varscan2
- KIF21B | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 69/109 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1262345783, COSV59759336; called by muse, mutect2, varscan2
- KIF22 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV50715457; called by muse, mutect2, varscan2
- KIF26B | c.4030T>A p.S1344T | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV100832236; called by muse, mutect2, varscan2
- KIF26B | c.4031C>T p.S1344F | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV100832238; called by muse, mutect2
- KIR3DL1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs777577843, COSV58492751; called by muse, varscan2
- KLF5 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs774556061, COSV100890535; called by muse, mutect2, varscan2
- KLF5 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100890537; called by muse, mutect2, varscan2
- KLHL13 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV53248901; called by muse, mutect2, varscan2
- KLHL14 | c.1787A>T p.K596I | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63833111; called by muse, mutect2, varscan2
- KLHL5 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); catalogued as COSV54674753, COSV54675158; called by muse, mutect2, varscan2
- KLHL6 | c.391T>A p.Y131N | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV58067033; called by muse, mutect2, varscan2
- KLK7 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV58344400; called by muse, mutect2, varscan2
- KLRK1 | c.222G>A p.W74* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV53698782; called by muse, mutect2, varscan2
- KRT1 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV52867311; called by muse, mutect2, varscan2
- KRT36 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.273); catalogued as COSV60202459; called by muse, mutect2, varscan2
- KRT38 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs148366219; called by muse, mutect2, varscan2
- KRT80 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1411383672, COSV57549790; called by muse, mutect2, varscan2
- KRTAP10-10 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV59966217; called by muse, mutect2, varscan2
- KRTAP3-1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66957530; called by muse, mutect2, varscan2
- LAD1 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 156/281 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.138); catalogued as rs143101113; called by muse, varscan2
- LAIR1 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs141229178; called by muse, mutect2, varscan2
- LAMA3 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV58070475; called by muse, mutect2, varscan2
- LAMA3 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.149); catalogued as COSV58070481; called by muse, mutect2, varscan2
- LAS1L | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV56707703; called by muse, mutect2, varscan2
- LCT | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.72); catalogued as rs1262862383, COSV51551115; called by muse, mutect2, varscan2
- LCT | c.2426C>T p.S809F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as COSV51551136; called by muse, mutect2, varscan2
- LEP | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.156); catalogued as COSV58241129; called by muse, mutect2, varscan2
- LIG4 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV63597235; called by muse, mutect2, varscan2
- LILRB3 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1223421126; called by muse, mutect2, varscan2
- LPA | c.2503C>T p.R835* | Nonsense Mutation (SNP) | VAF 109/276 reads (39%) | catalogued as rs746733669, COSV100305985; called by muse, mutect2, varscan2
- LPIN3 | c.1177A>T p.N393Y | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); catalogued as COSV64718709; called by muse, mutect2, varscan2
- LPIN3 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64718715; called by muse, mutect2, varscan2
- LRBA | c.5833C>T p.R1945C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752669335, COSV63956951; called by muse, mutect2, varscan2
- LRCH3 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV58392809; called by muse, mutect2, varscan2
- LRFN2 | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.124); catalogued as rs748123889, COSV57828564; called by muse, mutect2, varscan2
- LRP1B | c.13129G>A p.D4377N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as rs150457308, COSV67191226, COSV67231460, COSV67274376; called by muse, mutect2, varscan2
- LRP1B | c.10001G>A p.W3334* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV67231465; called by muse, mutect2, varscan2
- LRP1B | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.475); catalogued as COSV67231473; called by muse, mutect2, varscan2
- LRP1B | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs537488472, COSV67201409; called by muse, mutect2, varscan2
- LRP2 | c.13633G>A p.E4545K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV55544160; called by muse, mutect2, varscan2
- LRP2 | c.4940C>T p.A1647V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV55557388; called by muse, mutect2, varscan2
- LRRC37B | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | catalogued as COSV58952793; called by muse, mutect2, varscan2
- LRRC3B | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV67521365; called by muse, mutect2, varscan2
- LRRC49 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs199883910, COSV53011514; called by muse, mutect2, varscan2
- LRRC4C | c.945G>A p.W315* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as rs151083424, COSV53427812; called by muse, mutect2, varscan2
- LRRIQ1 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV67832158, COSV67837048; called by muse, mutect2, varscan2
- LRTM2 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs776606825, COSV54565369; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 168/517 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.879); catalogued as COSV65442901; called by muse, mutect2, varscan2
- LYST | c.1778T>C p.I593T | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as COSV67708022; called by muse, mutect2, varscan2
- MACROD2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs778184364, COSV53987529; called by muse, mutect2, varscan2
- MAGEA10 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as COSV54884313; called by muse, mutect2, varscan2
- MAGEA11 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV60756217; called by muse, mutect2, varscan2
- MAGEA6 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 92/325 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61449066; called by muse, mutect2, varscan2
- MAGEA8 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 34/124 reads (27%) | catalogued as COSV54064281; called by muse, mutect2, varscan2
- MAGEB1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs751987621, COSV66775509, COSV66775753; called by muse, mutect2, varscan2
- MAGEB10 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV63311597; called by muse, mutect2, varscan2
- MAGEC1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.555); catalogued as rs765964046, COSV53574288; called by muse, mutect2, varscan2
- MAGEC2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs760812827, COSV55998133; called by muse, mutect2, varscan2
- MALT1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV61935146; called by muse, mutect2, varscan2
- MAP2 | c.4364G>A p.R1455K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.754); catalogued as COSV52294456; called by muse, mutect2, varscan2
- MAP3K21 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64043333; called by muse, mutect2, varscan2
- MAP3K21 | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV64041937; called by muse, mutect2, varscan2
- MAP4K1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.035); catalogued as COSV99943013; called by muse, mutect2
- MAP4K1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV99943014; called by muse, mutect2
- MAP4K4 | c.2482A>G p.T828A (on ENST00000347699 / NM_001242559.2; = p.T746A on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV56331705; called by muse, mutect2, varscan2
- MAPK4 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs745586840, COSV68542485, COSV68543504; called by muse, mutect2, varscan2
- MARCO | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59055292, COSV59059028; called by muse, mutect2, varscan2
- MBD5 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV68697479; called by muse, mutect2, varscan2
- MBTPS2 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.828); catalogued as COSV63411722; called by muse, mutect2
- MBTPS2 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs1393102443, COSV63411728; called by muse, mutect2, varscan2
- MCOLN2 | c.407A>T p.N136I | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV52296491; called by muse, mutect2, varscan2
- MCTP2 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs140445827; called by muse, mutect2, varscan2
- MED13 | c.5675T>A p.L1892H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67263989; called by muse, mutect2, varscan2
- MEGF10 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV57250509, COSV99174771; called by muse, mutect2, varscan2
- MFSD8 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV56551434; called by muse, mutect2, varscan2
- MGAM | c.2611C>A p.L871I | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV72074843, COSV72076111; called by muse, mutect2, varscan2
- MGAM | c.4708C>T p.R1570C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601326, COSV72074844; called by muse, mutect2, varscan2
- MGAM | c.5398G>A p.E1800K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs267601328, COSV72073671; called by mutect2, varscan2
- MGAT3 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57866048; called by muse, mutect2, varscan2
- MGAT4C | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749782221, COSV59833060; called by muse, mutect2, varscan2
- MGAT4C | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.553); catalogued as COSV59833581, COSV59837675; called by muse, mutect2, varscan2
- MICU2 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66674276; called by muse, mutect2, varscan2
- MIEF2 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs771744645, COSV59902069; called by muse, mutect2, varscan2
- MIS18BP1 | c.2902C>T p.L968F | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.405); catalogued as COSV60371324; called by muse, mutect2, varscan2
- MMD | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50434708; called by muse, mutect2, varscan2
- MMP10 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.092); catalogued as rs142065601; called by muse, mutect2, varscan2
- MMP27 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs187008697, COSV52781292; called by muse, mutect2, varscan2
- MMP9 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.784); catalogued as rs746759681, COSV63434105; called by muse, mutect2, varscan2
- MORC1 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs549951203, COSV51714451; called by muse, mutect2, varscan2
- MOV10L1 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV53173340; called by muse, mutect2, varscan2
- MPO | c.2170C>T p.P724S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51859755; called by muse, mutect2, varscan2
- MPP7 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.179); catalogued as rs147738330; called by muse, mutect2, varscan2
- MPRIP | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 65/221 reads (29%) | catalogued as COSV57927735; called by muse, mutect2, varscan2
- MROH2B | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV68181244; called by muse, mutect2, varscan2
- MSN | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.655); catalogued as COSV64303362; called by muse, mutect2, varscan2
- MTM1 | c.1711C>T p.L571F | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV60335453; called by muse, mutect2, varscan2
- MTUS2 | c.3853G>A p.E1285K (on ENST00000612955 / NM_001366650.1; = p.E264K on NM_015233.6) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1317321912, COSV66421518; called by muse, mutect2, varscan2
- MUC16 | c.21325C>T p.P7109S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67472411; called by muse, mutect2, varscan2
- MUC16 | c.8546C>T p.P2849L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV67472435; called by muse, mutect2, varscan2
- MUC16 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); catalogued as COSV67472441; called by muse, mutect2, varscan2
- MUC17 | c.11201C>T p.S3734F | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1444407122, COSV60279253, COSV60291415; called by muse, mutect2, varscan2
- MUSK | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs1349731741, COSV51899051; called by muse, mutect2, varscan2
- MUSK | c.735G>A p.W245* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | catalogued as COSV51888312; called by muse, mutect2, varscan2
- MUSK | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51884479; called by muse, mutect2, varscan2
- MXRA5 | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54238399; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, mutect2, varscan2
- MYCBP2 | c.11416C>T p.P3806S (on ENST00000357337; = p.P3844S on NM_015057.5) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as COSV62022764; called by muse, mutect2, varscan2
- MYCBPAP | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.695); catalogued as rs752523761, COSV52138729; called by muse, mutect2, varscan2
- MYEF2 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.776); catalogued as rs749890396, COSV51048575; called by muse, mutect2, varscan2
- MYH13 | c.4645G>A p.E1549K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52831365; called by muse, mutect2, varscan2
- MYH2 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV55440127; called by muse, mutect2, varscan2
- MYH3 | c.5687A>G p.K1896R | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.116); catalogued as rs1162608892, COSV56866102; called by muse, mutect2, varscan2
- MYH3 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV56866114; called by muse, mutect2, varscan2
- MYH4 | c.4850G>A p.R1617K | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV55115985, COSV55119624; called by muse, mutect2, varscan2
- MYH4 | c.4352G>A p.R1451K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV104370722, COSV55114667; called by muse, varscan2
- MYH7 | c.4429C>T p.L1477F | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62520190; called by muse, mutect2, varscan2
- MYH8 | c.4250T>C p.L1417P | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67966534; called by muse, mutect2, varscan2
- MYO16 | c.627A>T p.L209F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV51798961; called by muse, mutect2, varscan2
- MYO18B | c.6428C>T p.P2143L | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as rs766223723, COSV59136945; called by muse, mutect2, varscan2
- MYO3A | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV56334473; called by muse, mutect2, varscan2
- MYO3A | c.2670A>G p.I890M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV99779482; called by muse, mutect2, varscan2
- MYO3B | c.1780T>C p.F594L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58705827; called by muse, mutect2, varscan2
- MYO5B | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53220996; called by muse, mutect2, varscan2
- MYO9A | c.2896C>T p.H966Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1036122610, COSV61852325; called by muse, mutect2, varscan2
- MYOF | c.5632C>T p.R1878* | Nonsense Mutation (SNP) | VAF 19/68 reads (28%) | catalogued as rs779005999, COSV100825642; called by muse, mutect2, varscan2
- MYOM3 | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV58395079, COSV99044115; called by muse, mutect2, varscan2
- MYOM3 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs780256294, COSV58391082, COSV58395092; called by muse, mutect2, varscan2
- MYRF | c.265C>T p.P89S (on ENST00000278836 / NM_001127392.3; = p.P80S on NM_013279.4) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1007466699, COSV53889782; called by muse, mutect2, varscan2
- MYT1L | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67709081; called by muse, mutect2, varscan2
- NADK2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56937341; called by muse, mutect2
- NAP1L2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV65172605, COSV65172728; called by muse, varscan2
- NCKAP5L | c.3296C>T p.S1099L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs773815992, COSV60128893; called by muse, mutect2, varscan2
- NCOA3 | c.1417C>T p.L473F | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV59069561; called by muse, mutect2, varscan2
- NCOR2 | c.5582C>T p.S1861F | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62299269; called by muse, mutect2, varscan2
- NCOR2 | c.5381C>T p.S1794F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62299273; called by muse, mutect2, varscan2
- NDOR1 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs779205950, COSV100788964; called by muse, mutect2, varscan2
- NDRG1 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.924); catalogued as rs748984505, COSV60484320; called by muse, mutect2, varscan2
- NDUFS2 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV63488036; called by muse, mutect2, varscan2
- NEB | c.930G>A p.R310= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as COSV51424185; called by muse, mutect2
- NEBL | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV65803562; called by muse, mutect2
- NEBL | c.224A>T p.N75I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV101008963, COSV65799784; called by muse, mutect2, varscan2
- NECTIN3 | c.1139T>C p.L380P | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as rs761364043, COSV60551765; called by muse, mutect2, varscan2
- NEDD4L | c.530T>A p.V177D | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV56846467; called by muse, mutect2, varscan2
- NEFM | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV55332654; called by muse, mutect2, varscan2
- NEK11 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV53908948; called by muse, mutect2, varscan2
- NEK8 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV52045549; called by muse, mutect2, varscan2
- NEXMIF | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50038353; called by muse, mutect2, varscan2
- NEXMIF | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50038495, COSV99281601; called by muse, mutect2, varscan2
- NFXL1 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs753724802, COSV67431915; called by muse, mutect2, varscan2
- NLGN4X | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV52022277; called by muse, mutect2, varscan2
- NLRC4 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV61593082; called by muse, mutect2, varscan2
- NLRC5 | c.4481C>T p.S1494F | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.38); catalogued as COSV52656923; called by muse, mutect2, varscan2
- NLRP1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.268); catalogued as COSV52568451; called by muse, mutect2, varscan2
- NLRP11 | c.2735T>C p.V912A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.052); catalogued as COSV64087754; called by muse, mutect2, varscan2
- NLRP11 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as COSV64087759; called by muse, mutect2, varscan2
- NLRP13 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV61620393; called by muse, mutect2, varscan2
- NLRP2 | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as rs866085205, COSV54756252; called by muse, mutect2, varscan2
- NLRP2 | c.2400G>A p.W800* | Nonsense Mutation (SNP) | VAF 40/129 reads (31%) | catalogued as COSV54753880; called by muse, mutect2, varscan2
- NLRP4 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56708963; called by muse, mutect2, varscan2
- NLRP5 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.566); catalogued as COSV66765265; called by muse, mutect2, varscan2
- NLRP8 | c.2422C>T p.L808F | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.609); catalogued as COSV52588833; called by muse, mutect2, varscan2
- NLRP9 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs146896528, COSV60460056; called by muse, mutect2, varscan2
- NOD1 | c.915G>A p.W305* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV56112958; called by muse, mutect2, varscan2
- NOS1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV57614289; called by muse, mutect2, varscan2
- NOTCH1 | c.2629C>T p.P877S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53058193; called by mutect2, varscan2
- NOTCH3 | c.3580C>T p.P1194S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1265439284, COSV54637427; called by muse, mutect2, varscan2
- NOTCH4 | c.5711G>A p.G1904E | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV66681320; called by muse, mutect2, varscan2
- NPAP1 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs901343402, COSV61505232, COSV61507875; called by muse, mutect2, varscan2
- NPFFR2 | c.357G>A p.W119* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as rs1415011451, COSV58150598; called by muse, mutect2, varscan2
- NPFFR2 | c.707T>A p.F236Y | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV58150611; called by muse, mutect2, varscan2
- NPNT | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as COSV59754525; called by muse, mutect2, varscan2
- NPSR1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs568145224, COSV62202336; called by muse, mutect2, varscan2
- NREP | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1026566263, COSV57405486; called by muse, mutect2, varscan2
- NSUN7 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV57274359; called by muse, mutect2, varscan2
- NSUN7 | c.912G>A p.W304* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs1172386650, COSV57274371; called by muse, mutect2, varscan2
- NT5C1B | c.374C>T p.S125F (on ENST00000359846 / NM_001199086.2; = p.S65F on NM_033253.4) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV58396421; called by muse, mutect2, varscan2
- NT5DC2 | c.135dup p.E46Rfs*21 | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | catalogued as rs745545727; called by mutect2, pindel, varscan2
- NT5M | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV66518986; called by muse, mutect2, varscan2
- NTNG1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53974219; called by muse, mutect2, varscan2
- NTRK3 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV58126137; called by muse, mutect2, varscan2
- NUB1 | c.1661G>A p.G554E (on ENST00000568733 / NM_001243351.1; = p.G540E on NM_016118.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as COSV57840688; called by muse, mutect2, varscan2
- NUCB1 | c.516T>A p.H172Q | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); catalogued as COSV54386621; called by muse, mutect2, varscan2
- NUDT5 | c.136T>C p.W46R | Missense Mutation (SNP) | VAF 125/434 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66718525; called by muse, mutect2, varscan2
- NUP98 | c.2131C>T p.H711Y | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.358); catalogued as COSV61432327, COSV61433079; called by muse, mutect2, varscan2
- NUTM2D | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs1435628332, COSV67745981, COSV67746448; called by muse, mutect2, varscan2
- OASL | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 118/410 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.55); catalogued as COSV56567483; called by muse, mutect2, varscan2
- OLAH | c.326G>A p.R109K (on ENST00000378228 / NM_001039702.3; = p.R162K on NM_018324.3) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100984866, COSV65492768; called by muse, mutect2
- OPCML | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59425093, COSV59428586; called by muse, mutect2, varscan2
- OR10A3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs751844601, COSV62459225, COSV62459990; called by muse, mutect2, varscan2
- OR10G2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV73390395; called by muse, mutect2, varscan2
- OR10H5 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58278359; called by muse, mutect2, varscan2
- OR11H1 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1354826500, COSV99421760; called by mutect2, varscan2
- OR14A16 | c.61A>G p.M21V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs547883422, COSV62926785; called by muse, mutect2, varscan2
- OR14K1 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.376); catalogued as COSV51720761, COSV99315134; called by muse, mutect2, varscan2
- OR1J4 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.119); catalogued as rs768295097, COSV61589724, COSV61590203; called by muse, mutect2, varscan2
- OR2A1 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV101283380; called by muse, mutect2, varscan2
- OR2B3 | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV65851004; called by muse, mutect2, varscan2
- OR2T2 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.87); catalogued as COSV100737691, COSV61618957; called by muse, mutect2, varscan2
- OR2W1 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV65851664; called by muse, mutect2, varscan2
- OR4A15 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as COSV59035689; called by muse, mutect2, varscan2
- OR4A15 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1428184028, COSV59035680; called by muse, mutect2, varscan2
- OR4K1 | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV53458913, COSV53460428; called by muse, mutect2, varscan2
- OR4K14 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs992212775, COSV59292142; called by muse, mutect2
- OR4K5 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV60003852; called by muse, varscan2
- OR4K5 | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV60003858; called by muse, mutect2, varscan2
- OR4L1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV59850215; called by muse, mutect2, varscan2
- OR51A2 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100985050; called by muse, mutect2, varscan2
- OR52I2 | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV57044370; called by muse, mutect2, varscan2
- OR5H2 | c.722A>T p.K241I | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62350986; called by muse, mutect2, varscan2
- OR5H2 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as rs760137674, COSV62350994; called by muse, mutect2, varscan2
- OR5K1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs577765647, COSV60304367, COSV60304401; called by muse, mutect2, varscan2
- OR5P2 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs751172323, COSV61490283; called by muse, mutect2, varscan2
- OR5V1 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV65828412; called by muse, mutect2, varscan2
- OR6C4 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV67792883; called by muse, mutect2, varscan2
- OR6F1 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as rs1558302428, COSV57468156; called by muse, mutect2, varscan2
- OR9A2 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.665); catalogued as COSV63306693; called by muse, mutect2, varscan2
- OSM | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV53161511; called by muse, mutect2, varscan2
- OSMR | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1450788526, COSV57086203; called by muse, mutect2, varscan2
- OTOF | c.4021G>A p.E1341K (on ENST00000272371 / NM_194248.3; = p.E574K on NM_004802.4) | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.102); catalogued as rs1229086311, COSV55505745; called by muse, mutect2, varscan2
- PACSIN1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV55060525; called by muse, mutect2, varscan2
- PAK2 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59081904; called by muse, mutect2, varscan2
- PARD3 | c.4057C>T p.P1353S | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as COSV61059356; called by muse, mutect2, varscan2
- PARM1 | c.657A>T p.K219N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV56654676; called by muse, mutect2, varscan2
- PARP14 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs914724263, COSV71734838; called by muse, mutect2, varscan2
- PASD1 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV64855711; called by muse, mutect2, varscan2
- PAX8 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV54509489; called by muse, mutect2, varscan2
- PCARE | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV59055328, COSV59058799; called by muse, mutect2, varscan2
- PCDH15 | c.4964C>T p.S1655L (on ENST00000644397 / NM_001354429.2; = p.S1597L on NM_001142771.2) | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.07); catalogued as rs779212198, COSV64701115, COSV64703325; called by muse, mutect2, varscan2
- PCDH18 | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61269227, COSV61270908; called by muse, mutect2, varscan2
- PCDHA1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65374839; called by muse, mutect2, varscan2
- PCDHA5 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1554129247, COSV65350227; called by muse, mutect2, varscan2
- PCDHB1 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60631440; called by muse, mutect2, varscan2
- PCDHB1 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV60631450; called by muse, mutect2, varscan2
- PCLO | c.13526C>T p.S4509L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61640395; called by muse, mutect2, varscan2
- PCLO | c.12475C>T p.P4159S | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.909); catalogued as rs868287877, COSV61640409; called by muse, mutect2, varscan2
- PCNX1 | c.5593C>T p.H1865Y | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53088572, COSV53092272; called by muse, mutect2, varscan2
- PCNX2 | c.1470G>A p.W490* | Nonsense Mutation (SNP) | VAF 43/90 reads (48%) | catalogued as COSV50810734; called by muse, mutect2, varscan2
- PCSK1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60733960; called by muse, mutect2, varscan2
- PCSK5 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.099); catalogued as COSV65090297; called by muse, mutect2, varscan2
- PCYT1A | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53057981; called by muse, mutect2, varscan2
- PDCD4 | c.62A>G p.D21G | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV54523349; called by muse, mutect2, varscan2
- PDE1A | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs775065809, COSV59521241; called by muse, mutect2, varscan2
- PDE3A | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100762043, COSV62974825, COSV62977746; called by muse, mutect2, varscan2
- PDE4A | c.2653C>T p.P885S (on ENST00000380702 / NM_001111307.2; = p.P646S on NM_006202.3) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53357211; called by muse, mutect2, varscan2
- PDE4DIP | c.5657C>T p.T1886I | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV57700202; called by mutect2, varscan2
- PDE6B | c.2022G>A p.K674= | Splice Region (SNP) | VAF 31/86 reads (36%) | catalogued as COSV55327234; called by muse, mutect2, varscan2
- PDZD2 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV56860797; called by muse, mutect2, varscan2
- PEAK1 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56937262; called by muse, mutect2, varscan2
- PGM5 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs782436052, COSV101123427; called by muse, mutect2, varscan2
- PHF14 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV68855236; called by muse, mutect2, varscan2
- PHF21B | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV57558991; called by muse, mutect2, varscan2
1,042 further variants in this file (392 protein-altering or splice-affecting, 601 silent, 49 other) are not listed here.
